MMRF case MMRF_1664 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a5e50950-146d-45cf-adea-c9ae1366360e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.9 years (23,322 days); ISS stage: II; Days to last known disease status: 1,194 days (3.3 years); Days to last follow up: 1,194 days (3.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 940 days (2.6 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 17 days; Days to treatment end: 676 days (1.9 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 174 days; Days to treatment end: 175 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 177 days; Days to treatment end: 177 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 926 days (2.5 years); Days to treatment end: 926 days (2.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 941 days (2.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 15 (ECOG 0): M Protein 3.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 28.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.7 mg/dL; Immunoglobulin G 2.7 g/L; Immunoglobulin A 37 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 3.21 µg/mL; Hemoglobin 5.7 mmol/L; Leukocytes 16.1 ×10⁹/L; Absolute Neutrophil 14.8 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 165 µmol/L; Blood Urea Nitrogen 19.6 mmol/L; Calcium 2.43 mmol/L; Albumin 33 g/L; Total Protein 9.7 g/dL; Glucose 6.38 mmol/L.
- Day 101 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 2.87 g/L; Immunoglobulin A 1.13 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.35 µg/mL; Lactate Dehydrogenase 6.92 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 4.29 mmol/L.
- Day 283 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 5.99 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.66 g/L; Beta 2 Microglobulin 2.36 µg/mL; Hemoglobin 9.3 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 3.91 mmol/L.
- Day 387 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 2.7 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 2.77 µg/mL; Hemoglobin 6.57 mmol/L; Leukocytes 1.2 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 49 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.03 mmol/L; Albumin 28 g/L; Total Protein 5 g/dL; Glucose 5.34 mmol/L.
- Day 458 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 3.27 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 2.41 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 71 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 5.7 g/dL; Glucose 4.29 mmol/L.
- Day 549 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 2.7 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.47 µg/mL; Lactate Dehydrogenase 8.39 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 64 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.13 mmol/L; Albumin 32 g/L; Total Protein 5.4 g/dL; Glucose 4.24 mmol/L.
- Day 648 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 2.7 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.24 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 51 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 1.95 mmol/L; Albumin 30 g/L; Total Protein 5.1 g/dL; Glucose 4.13 mmol/L.
- Day 717 (ECOG 1): Hemoglobin 7.07 mmol/L; Leukocytes 1.7 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 48 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.03 mmol/L; Albumin 34 g/L; Total Protein 5.2 g/dL; Glucose 6.22 mmol/L.
- Day 851: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 3.6 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 1.7 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 57 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 5.4 g/dL; Glucose 3.91 mmol/L.
- Day 934 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 4.51 g/L; Immunoglobulin A 1.13 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.07 µg/mL; Lactate Dehydrogenase 7.68 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 1.6 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 62 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 5.5 g/dL; Glucose 6 mmol/L.
- Day 1,019 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 5.4 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 6.92 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 90 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.08 mmol/L; Albumin 32 g/L; Total Protein 5.4 g/dL; Glucose 4.84 mmol/L.
- Day 1,104 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.71 mg/dL; Immunoglobulin G 5.01 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 93 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 5.5 g/dL; Glucose 4.46 mmol/L.
- Day 1,194 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 6.59 g/L; Immunoglobulin A 1.51 g/L; Immunoglobulin M 0.199 g/L; Beta 2 Microglobulin 2.81 µg/mL; Hemoglobin 8.87 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.48 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 4.13 mmol/L.

Other clinical attributes
- Day 15: Weight: 96 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples)
- Sample MMRF_1664_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 15 days.
- Sample MMRF_1664_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 15 days.
